Somatic mutation profile of tumor specimen MMRF_1393_1_BM_CD138pos (aliquot MMRF_1393_1_BM_CD138pos_T1_KAS5U_L01704) from MMRF case MMRF_1393, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 58.5 years (21,357 days).
Specimen MMRF_1393_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5b9c4831-797a-441b-987a-4f8d86f50d4b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1393_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1393_1_PB_Whole_C2_KAS5U_L01712; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e72c116a-02d5-48fb-ab71-247a595dedd1

The open-access MAF lists 73 somatic variants for this specimen: 33 protein-altering or splice-affecting, 5 silent, 35 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, 3'UTR 18, Intron 8, Silent 5, 3'Flank 3, 5'UTR 3, RNA 2, In Frame Del 1, 5'Flank 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 43/79 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AGXT2 | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 60/177 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.096); catalogued as COSV51484516; called by muse, mutect2, varscan2
- ARHGAP20 | c.3527C>T p.P1176L | Missense Mutation (SNP) | VAF 86/298 reads (29%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as COSV52811061; called by muse, mutect2, varscan2
- C10orf71 | c.3292C>T p.P1098S | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.138); catalogued as rs1253576800; called by muse, mutect2, varscan2
- FBXL7 | c.1415G>A p.R472H | Missense Mutation (SNP) | VAF 37/67 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs766213544, COSV61651751; called by muse, mutect2, varscan2
- IGHV1-69 | c.219C>G p.I73M | Missense Mutation (SNP) | VAF 62/99 reads (63%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs376252778; called by muse, mutect2, varscan2
- IGHV2-70 | c.268A>C p.I90L | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.2); catalogued as rs372477786; called by muse, varscan2
- IGHV2-70 | c.179A>G p.Q60R | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.052); catalogued as rs539008662; called by muse, varscan2
- IGHV2-70 | c.92T>C p.V31A | Missense Mutation (SNP) | VAF 42/82 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as rs370193821; called by muse, varscan2
- IGLV3-1 | c.107C>T p.T36I | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs750483717; called by muse, varscan2
- KCTD15 | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV52289817; called by muse, mutect2, varscan2
- MYH7 | c.4823G>A p.R1608H | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.179); catalogued as rs587779391, CM127954, COSV62521586; called by muse, mutect2, varscan2
- PODN | c.71C>T p.S24L | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as rs761072151, COSV100439621; called by muse, mutect2, varscan2
- PRR16 | c.605G>A p.R202Q (on ENST00000407149 / NM_001300783.2; = p.R179Q on NM_016644.2) | Missense Mutation (SNP) | VAF 51/228 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs756220018, COSV65405069; called by muse, mutect2, varscan2
- RHOV | c.341A>C p.Q114P | Missense Mutation (SNP) | VAF 74/222 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.068); catalogued as COSV55027410; called by muse, mutect2, varscan2
- TIAM1 | c.3613G>A p.A1205T | Missense Mutation (SNP) | VAF 67/142 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.104); catalogued as rs529598323, COSV54543783; called by muse, mutect2, varscan2
- CACNA1G | c.6403G>A p.A2135T | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- CCDC157 | c.2257T>A p.*753Kext*6 | Nonstop Mutation (SNP) | VAF 28/53 reads (53%) | called by muse, mutect2, varscan2
- GPR158 | c.3169G>A p.V1057I | Missense Mutation (SNP) | VAF 54/119 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GRM4 | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- IGLV3-1 | c.37T>G p.Y13D | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- IPCEF1 | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 9/213 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.06); called by muse, mutect2
- KAT6A | c.3324_3335del p.E1109_E1112del | In Frame Del (DEL) | VAF 67/184 reads (36%) | called by mutect2, varscan2
- KCNH5 | c.1315G>A p.A439T | Missense Mutation (SNP) | VAF 76/181 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- KIF11 | c.67G>C p.V23L | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- LY6E | c.92G>A p.S31N | Missense Mutation (SNP) | VAF 82/190 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.061); called by muse, mutect2
- MRPL37 | c.236A>G p.D79G | Missense Mutation (SNP) | VAF 66/170 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- RASGEF1B | c.1154A>G p.N385S | Missense Mutation (SNP) | VAF 5/149 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); called by muse, mutect2
- SPEF2 | c.566G>T p.R189I | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.307); called by muse, mutect2
- TAS2R16 | c.849G>T p.L283F | Missense Mutation (SNP) | VAF 122/277 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TFAP2C | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TMEM176A | c.353G>A p.R118K | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- TSPAN2 | c.227G>C p.G76A | Missense Mutation (SNP) | VAF 48/146 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACAP3 | c.1404A>C p.L468= | Silent (SNP) | VAF 37/84 reads (44%) | called by muse, mutect2, varscan2
- DXO | c.330C>T p.L110= | Silent (SNP) | VAF 30/53 reads (57%) | catalogued as rs371295094; called by muse, mutect2, varscan2
- OR8D2 | c.735C>A p.L245= | Silent (SNP) | VAF 112/312 reads (36%) | called by muse, mutect2, varscan2
- PLEKHA6 | c.639C>T p.G213= | Silent (SNP) | VAF 33/74 reads (45%) | called by muse, mutect2, varscan2
- XPNPEP3 | c.75G>A p.L25= | Silent (SNP) | VAF 62/118 reads (53%) | called by muse, mutect2, varscan2
- ACO2 | c.1138+195C>T | Intron (SNP) | VAF 5/19 reads (26%) | called by muse, mutect2
- ASTN1 | c.*935G>C | 3'UTR (SNP) | VAF 22/53 reads (42%) | called by muse, mutect2, varscan2
- ATP2A1 | c.*148G>A | 3'UTR (SNP) | VAF 136/276 reads (49%) | catalogued as rs1026173184, COSV62871427; called by muse, mutect2, varscan2
- ATP8A1 | c.*1168T>G | 3'UTR (SNP) | VAF 41/88 reads (47%) | called by muse, varscan2
- BCL7A | chr12:122021523 T>C | 5'Flank (SNP) | VAF 27/58 reads (47%) | catalogued as COSV55848356; called by muse, mutect2, varscan2
- CALHM5 | c.*4100T>G | 3'UTR (SNP) | VAF 52/126 reads (41%) | called by muse, mutect2, varscan2
- CPSF6 | c.694+220T>A | Intron (SNP) | VAF 40/90 reads (44%) | called by muse, mutect2, varscan2
- DOCK5 | c.*689T>G | 3'UTR (SNP) | VAF 52/154 reads (34%) | called by muse, mutect2, varscan2
- DPYD | c.*345T>A | 3'UTR (SNP) | VAF 24/64 reads (38%) | called by muse, mutect2, varscan2
- DPYSL3 | c.*2069C>T | 3'UTR (SNP) | VAF 40/97 reads (41%) | called by muse, mutect2, varscan2
- ERICH3 | c.2176+236C>T | Intron (SNP) | VAF 11/68 reads (16%) | catalogued as rs900027518; called by muse, mutect2, varscan2
- FJX1 | c.-136C>T | 5'UTR (SNP) | VAF 15/50 reads (30%) | called by muse, mutect2, varscan2
- GDA | c.*1790C>T | 3'UTR (SNP) | VAF 27/67 reads (40%) | catalogued as rs7042164; called by muse, mutect2, varscan2
- HNRNPH3 | c.*985G>A | 3'UTR (SNP) | VAF 18/116 reads (16%) | called by muse, mutect2, varscan2
- IGKV2-29 | n.108G>C | RNA (SNP) | VAF 46/172 reads (27%) | called by muse, varscan2
- IGKV2-29 | n.107G>A | RNA (SNP) | VAF 46/172 reads (27%) | called by muse, varscan2
- IGLL5 | c.-96C>A | 5'UTR (SNP) | VAF 23/46 reads (50%) | catalogued as COSV73250060, COSV73250979; called by muse, mutect2, varscan2
- MTURN | c.162+2203G>A | Intron (SNP) | VAF 40/108 reads (37%) | called by muse, mutect2, varscan2
- MYO1E | c.-94A>G | 5'UTR (SNP) | VAF 52/83 reads (63%) | called by muse, mutect2, varscan2
- NDRG3 | c.*1063A>C | 3'UTR (SNP) | VAF 116/183 reads (63%) | called by muse, mutect2, varscan2
- NELL2 | c.1998+193T>C | Intron (SNP) | VAF 105/265 reads (40%) | called by muse, mutect2, varscan2
- PLEKHA2 | c.*1663T>C | 3'UTR (SNP) | VAF 35/92 reads (38%) | catalogued as rs1039877592; called by muse, mutect2, varscan2
- POU6F2 | chr7:39468583 A>T | 3'Flank (SNP) | VAF 26/53 reads (49%) | called by muse, mutect2, varscan2
- PRKG1 | c.*1513G>T | 3'UTR (SNP) | VAF 40/97 reads (41%) | called by muse, mutect2, varscan2
- PTBP3 | chr9:112218781 G>A | 3'Flank (SNP) | VAF 34/166 reads (20%) | called by muse, mutect2, varscan2
- RTN4 | c.*826A>G | 3'UTR (SNP) | VAF 40/90 reads (44%) | called by muse, mutect2, varscan2
- SLITRK3 | c.*450C>T | 3'UTR (SNP) | VAF 50/139 reads (36%) | called by muse, mutect2, varscan2
- STK11IP | c.2869+17G>T | Intron (SNP) | VAF 37/78 reads (47%) | called by muse, mutect2, varscan2
- SULF1 | c.*408A>G | 3'UTR (SNP) | VAF 300/691 reads (43%) | called by muse, mutect2, varscan2
- TACC2 | c.*408G>A | 3'UTR (SNP) | VAF 6/21 reads (29%) | called by muse, mutect2
- TCAF1 | c.*1371T>G | 3'UTR (SNP) | VAF 80/407 reads (20%) | called by muse, mutect2, varscan2
- TGFBI | c.1411-130T>G | Intron (SNP) | VAF 17/77 reads (22%) | called by muse, mutect2
- UBC | c.-4+61C>T | Intron (SNP) | VAF 61/119 reads (51%) | catalogued as rs555065082; called by muse, mutect2, varscan2
- VANGL1 | chr1:115691991 G>A | 3'Flank (SNP) | VAF 42/129 reads (33%) | called by muse, mutect2, varscan2
- VPS13A | c.*1372T>C | 3'UTR (SNP) | VAF 46/146 reads (32%) | called by muse, mutect2, varscan2
